Somatic mutation profile of tumor specimen ALCH-B3A2-TTP1-A (aliquot ALCH-B3A2-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B3A2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.0 years (27,774 days).
Specimen ALCH-B3A2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6f05070-4511-44c9-a2ac-16abe7825b59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3A2-NB1-A (Blood Derived Normal), aliquot ALCH-B3A2-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02c539f0-0093-4dad-8132-2e2e00fafada

The open-access MAF lists 54 somatic variants for this specimen: 32 protein-altering or splice-affecting, 16 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 16, Splice Region 3, 3'UTR 2, Intron 2, RNA 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 395/839 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ANKRD18B | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs543361569; called by muse, mutect2
- ATXN1L | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 58/590 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs974408321; called by muse, mutect2
- CCDC168 | c.11744T>C p.M3915T | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV59426079; called by muse, mutect2
- COPRS | c.338A>G p.N113S | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs758959262; called by muse, mutect2
- F5 | c.4643A>T p.D1548V | Missense Mutation (SNP) | VAF 35/842 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs750707854; called by muse, mutect2
- HEG1 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs746472724; called by muse, mutect2
- MAPK8IP3 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs374099237; called by muse, mutect2, varscan2
- MSN | c.1089A>G p.Q363= | Splice Region (SNP) | VAF 29/180 reads (16%) | catalogued as rs750794986; called by muse, mutect2, varscan2
- RBM10 | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | catalogued as COSV61309421, COSV61312659; called by muse, mutect2
- RUNX1T1 | c.1198G>A p.E400K (on ENST00000265814 / NM_001198628.1; = p.E373K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/864 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); catalogued as rs1266909547; called by muse, mutect2
- SCML1 | c.256G>T p.V86F (on ENST00000380041 / NM_001037540.3; = p.V59F on NM_006746.6) | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1357029716; called by muse, mutect2
- SPAST | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM164813; called by muse, mutect2
- TKT | c.1442A>G p.Y481C | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782787291, COSV56245677; called by muse, mutect2
- TMTC4 | c.515G>A p.R172H (on ENST00000376234 / NM_001350577.2; = p.R191H on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779545369; called by muse, mutect2
- ZNF776 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 40/421 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1299818398; called by muse, mutect2
- AACS | c.1122-7A>G | Splice Region (SNP) | VAF 11/185 reads (6%) | called by muse, mutect2
- AACS | c.1122-5C>T | Splice Region (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
- ARHGAP42 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2
- CERS2 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HUWE1 | c.5806C>T p.P1936S | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- IGLV4-3 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 27/460 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2
- LRCH2 | c.1891C>G p.P631A | Missense Mutation (SNP) | VAF 12/424 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- MC3R | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 55/604 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2
- MN1 | c.647G>A p.S216N | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPHOSPH10 | c.42T>G p.C14W | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ORM2 | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.175); called by muse, mutect2
- RAG1 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- SRGAP2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 34/395 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SWAP70 | c.1409A>G p.E470G | Missense Mutation (SNP) | VAF 62/554 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UGCG | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF609 | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2
- CDC25B | c.720C>T p.D240= (on ENST00000245960 / NM_021873.3; = p.D226= on NM_004358.4) | Silent (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- DEAF1 | c.1467C>T p.N489= | Silent (SNP) | VAF 19/282 reads (7%) | catalogued as rs1311371710; called by muse, mutect2
- DNAAF1 | c.661A>C p.R221= | Silent (SNP) | VAF 86/648 reads (13%) | called by muse, mutect2, varscan2
- FAM187B | c.999G>A p.G333= | Silent (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- ITGAD | c.300C>T p.G100= | Silent (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- ITGAE | c.2970C>T p.L990= | Silent (SNP) | VAF 14/272 reads (5%) | called by muse, mutect2
- LPA | c.3960G>A p.R1320= | Silent (SNP) | VAF 36/565 reads (6%) | called by muse, mutect2
- OTOF | c.5052G>A p.E1684= (on ENST00000272371 / NM_194248.3; = p.E917= on NM_004802.4) | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs1558469119; called by muse, mutect2
- PARP4 | c.1860G>A p.L620= | Silent (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
- RP1L1 | c.3870G>A p.E1290= | Silent (SNP) | VAF 105/804 reads (13%) | called by muse, varscan2
- SLC6A1 | c.297G>T p.L99= | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2
- SMARCA4 | c.3813C>T p.F1271= | Silent (SNP) | VAF 10/306 reads (3%) | catalogued as rs925020844, COSV60799676; ClinVar: likely benign; called by muse, mutect2
- TADA3 | c.393G>A p.Q131= | Silent (SNP) | VAF 7/112 reads (6%) | catalogued as rs919035512; called by muse, mutect2
- TFB1M | c.160C>T p.L54= | Silent (SNP) | VAF 60/734 reads (8%) | called by muse, mutect2
- WDR45 | c.759C>T p.C253= (on ENST00000376372 / NM_001029896.2; = p.C254= on NM_007075.3) | Silent (SNP) | VAF 32/246 reads (13%) | catalogued as rs782478405; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF592 | c.1650G>A p.L550= | Silent (SNP) | VAF 20/445 reads (4%) | catalogued as COSV55439134; called by muse, mutect2
- CASP16P | chr16:3148372 T>A | 3'Flank (SNP) | VAF 17/291 reads (6%) | called by muse, mutect2
- CD72 | c.262+44del | Intron (DEL) | VAF 7/57 reads (12%) | called by mutect2, pindel, varscan2
- FAM183BP | n.517C>T | RNA (SNP) | VAF 12/118 reads (10%) | catalogued as rs1160483470; called by muse, mutect2
- KRBA2 | c.*9369C>G | 3'UTR (SNP) | VAF 14/396 reads (4%) | called by muse, mutect2
- NPPA | c.*15G>A | 3'UTR (SNP) | VAF 21/456 reads (5%) | catalogued as rs1472810962; called by muse, mutect2
- ZFHX3 | c.-533+269A>T | Intron (SNP) | VAF 29/258 reads (11%) | called by muse, mutect2, varscan2
